Surgical pathology report (de-identified scan), TCGA case TCGA-AH-6643, project TCGA-READ (Rectum Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-AH-6643-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

Histopathological Examination

Path#: [REDACTED]

Pre-Op Diagnosis : Diverticulitis
Order Physician : [REDACTED]
Specimens : Colon Segment, sigmoid colon upper rectum specimen for [REDACTED]
out at [REDACTED]
Anastamotic Rings

Frozen Diagnosis :

Report : GROSS EXAMINATION:

A. The specimen is received in a container labeled with the name of the patient and identified as colon segment, sigmoid and upper rectum.

Length: 24 cm

Circumference: Up to 10.5 cm

Margins: Stapled

Serosa: Adhesions

Mass:

Size: 8.5 x 7.4 x 6.3 cm

Type: Polypoid

Distance from closest mucosal margin: 4.1 cm

Circumference: 99%

Depth of Invasion: Extends through the wall

Distance from Radial Margin: Grossly 0.7 cm

Comment: Located 3 cm from the opposite mucosal margin is a polyp measuring 1 x 0.8 x 0.8 cm. The mass is above the peritoneal reflection.

Block Summary: Closest mucosal margin 1, opposite mucosal margin 2, radial margin and mass 3-4, additional sections of mass 5-8, additional polyp 9-10, random sections 11, possible lymph nodes 12-14.

B. The specimen is received in a container labeled with the name of the patient and identified as anastomotic rings. Received on a silver colored metal and blue plastic device are two complete segments of colon tissue measuring 1.9 cm and 2.2 cm in greatest dimension. Representative sections submitted for routine processing. [REDACTED]

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Path #: [REDACTED]
Visit #: [REDACTED]

Page 1 of 2

[page 2 of 2]
DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

A. Colon, sigmoid colon and upper rectum, resection:
- 8.5 cm moderately differentiated adenocarcinoma, see
underlying cancer case summary checklist.
[T-59600 M-81403 154.1 P3-44090]

B. Anastomotic rings:
- No pathologic abnormality.
[T-59000 M-00110 V71.9 P3-44040]

CANCER CASE SUMMARY CHECKLIST

SPECIMEN: Sigmoid colon and upper rectum
PROCEDURE: Rectosigmoid colon (low anterior resection)
SPECIMEN LENGTH: 24 cm
TUMOR SITE: Rectosigmoid junction
TUMOR SIZE: 8.5 x 7.4 x 6.3 cm
MACROSCOPIC TUMOR PERFORATION: Not identified.
MACROSCOPIC INTACTNESS OF MESORECTUM: N/A
HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: Low-grade, moderately differentiated
MICROSCOPIC TUMOR EXTENSION: Invades through the muscularis
propria into the subserosal adipose tissue but does not
extend through the serosal surface.
MARGINS: Proximal margin: Uninvolved.
Distal margin: Uninvolved.
Circumferential margin: Uninvolved.
Distance of tumor from closest margin: Serosal margin, 4 mm
(block A8)
TREATMENT EFFECT: No prior treatment
LYMPH-VASCULAR INVASION: Not identified.
PERINEURAL INVASION: Not identified.
TUMOR DEPOSITS: Present
PATHOLOGIC STAGING (pTNM):
Primary Tumor (pT): pT3: Tumor invades through the
muscularis propria.
Regional Lymph Nodes (pN): pN2b: Metastasis in 7 or more
regional lymph nodes.
Number examined: 15
Number involved: 8
Distant Metastasis (pM): Not applicable.
ADDITIONAL PATHOLOGIC FINDINGS: Tubular adenoma, serosal
adhesions

COMMENT:

Intradepartmental consultation obtained. This case was
delayed to submit additional lymph nodes. Findings discussed
with [REDACTED]

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Path #: [REDACTED]
Visit #: [REDACTED]

Page 2 of 2

Source: NCI Genomic Data Commons file 6dee6fcc-c1db-42ab-803b-1289ebda195b (TCGA-AH-6643.9410D529-2067-464F-9EF5-ECF6C56CAAD9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).